PECGS case C083-000016 — USC PE-CGS: Optimizing Engagement of Hispanic Colorectal Cancer Patients in Cancer Genomic Characterization Studies (PECGS-COPECC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/58e6835d-d82c-4206-acae-3796cf7dc85b

Demographics
Sex at birth: female; Age at index: 39 years; Year of birth: 1982; Vital status: Dead; Cause of death: Cancer Related; Education level: Vocational College or Some College.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Sigmoid colon; Age at diagnosis: 39.3 years (14,354 days); AJCC clinical stage: Stage IVB; AJCC pathologic stage: Stage IVB; Progression or recurrence: yes; Days to last follow up: 440 days (1.2 years).

Other clinical attributes
- Menopause status: Premenopausal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0.

Biospecimens (2 samples)
- Sample C083-000016_Germline: Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample C083-000016_Tumor: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
